National Lung Screening Trial (NLST) participant 118284 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 58 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 27): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 30 effective mAs, display field of view 32 cm, reconstruction filter Siemens, other.
- T1 (day 623): Negative screen, significant abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, 40 effective mAs, display field of view 35 cm, reconstruction filter Siemens B30 / Siemens B50F.
- T2 (day 958): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, 40 effective mAs, display field of view 34 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (11 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 6 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 90.
- T0 abnormality 2: Other potentially significant abnormality below the diaphragm.
- T0 abnormality 3: Other minor abnormality noted.
- T1 abnormality 1: Other potentially significant abnormality above the diaphragm; pre-existing on earlier images (earliest visible day 27); interval change warrants further investigation.
- T1 abnormality 2: Significant cardiovascular abnormality; whether pre-existing could not be determined.
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left upper lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation ground glass; greatest diameter on CT slice 59; new (not pre-existing on earlier images).
- T2 abnormality 2: Significant cardiovascular abnormality; pre-existing on earlier images (earliest visible day 623); interval change does not warrant further investigation.
- T2 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 4: Other minor abnormality noted.
- T2 abnormality 5: Other minor abnormality noted.
- T2 abnormality 6: Emphysema.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,539.
